Somatic mutation profile of tumor specimen TCGA-A3-3357-01A (aliquot TCGA-A3-3357-01A-02D-1421-08) from TCGA case TCGA-A3-3357, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 62.5 years (22,825 days).
Specimen TCGA-A3-3357-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73b5cb1b-6811-4766-b287-952f494259f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3357-11A (Solid Tissue Normal), aliquot TCGA-A3-3357-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d8dc699-2b79-41ef-92cd-21aa9a82cade

The open-access MAF lists 103 somatic variants for this specimen: 78 protein-altering or splice-affecting, 25 silent.
By variant classification: Missense Mutation 63, Silent 25, Nonsense Mutation 5, Frame Shift Del 5, Frame Shift Ins 2, Splice Region 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3145G>C p.G1049R | Missense Mutation (SNP) | VAF 40/137 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as rs121913277, CM126700, COSV55874453, COSV55878564, COSV55919873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.50737C>T p.R16913* (on ENST00000591111; = p.R9489* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 23/98 reads (23%) | catalogued as rs1483931960, COSV59888643; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.3772T>C p.F1258L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.92); catalogued as COSV58144413; called by muse, mutect2, varscan2
- AK2 | c.197C>A p.A66E (on ENST00000354858; = p.A108E on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV61469792; called by muse, mutect2, varscan2
- ARHGAP31 | c.418C>G p.P140A | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as COSV51798020, COSV51798091, COSV99956673; called by muse, mutect2, varscan2
- ASB4 | c.488-1G>T p.X163_splice | Splice Site (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100367187; called by muse, mutect2
- ATP8B4 | c.204A>T p.L68= | Splice Region (SNP) | VAF 25/92 reads (27%) | catalogued as COSV52722944; called by muse, mutect2, varscan2
- BRWD1 | c.1871G>C p.G624A | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV60901849; called by muse, mutect2, varscan2
- C3AR1 | c.764A>T p.Y255F | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV50823329; called by muse, mutect2, varscan2
- CCDC73 | c.1076A>G p.N359S | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as COSV58803758; called by muse, mutect2, varscan2
- CCNB1IP1 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.418); catalogued as COSV62302716, COSV62303380; called by muse, mutect2, varscan2
- CEP135 | c.3338A>C p.E1113A | Missense Mutation (SNP) | VAF 156/542 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57262437; called by muse, mutect2, varscan2
- CLIP2 | c.2001G>T p.L667F | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56285167; called by muse, mutect2, varscan2
- COL4A4 | c.2830C>A p.P944T | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.067); catalogued as COSV61629607, COSV61635903; called by muse, mutect2, varscan2
- COL9A1 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 77/442 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs774360157, COSV61831785; called by muse, mutect2, varscan2
- COPG1 | c.1606G>C p.E536Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.95); PolyPhen benign (0.018); catalogued as COSV100135552, COSV59116301; called by muse, mutect2, varscan2
- CTC1 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1456198284, COSV59855076; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCT | c.1438C>G p.L480V | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.452); catalogued as COSV65467970, COSV65470545; called by muse, mutect2, varscan2
- DENND1B | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52471566; called by muse, mutect2
- DPYSL3 | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV58330456; called by muse, mutect2, varscan2
- EIF4A2 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 93/305 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56218448; called by muse, mutect2, varscan2
- ERCC6 | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 111/341 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.058); catalogued as COSV63393821; called by muse, mutect2, varscan2
- FBXW11 | c.1196T>C p.L399P | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51613273; called by muse, mutect2, varscan2
- FCHSD1 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV71301791; called by muse, mutect2, varscan2
- FRMD3 | c.537C>A p.F179L | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.241); catalogued as COSV100418432, COSV58468143; called by muse, mutect2, varscan2
- GCNT4 | c.25A>C p.K9Q | Missense Mutation (SNP) | VAF 231/523 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.312); catalogued as COSV59281627; called by muse, mutect2, varscan2
- GGT7 | c.1985T>G p.L662R | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); catalogued as COSV60542513; called by muse, varscan2
- GPR89A | c.1357A>G p.M453V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV100572461; called by mutect2, varscan2
- HERC1 | c.9426T>A p.G3142= | Splice Region (SNP) | VAF 23/88 reads (26%) | catalogued as COSV101496835, COSV71249890; called by muse, mutect2, varscan2
- HMCN1 | c.10316C>G p.S3439* | Nonsense Mutation (SNP) | VAF 24/189 reads (13%) | catalogued as COSV54919551, COSV54934899; called by muse, mutect2, varscan2
- IFIH1 | c.1056A>C p.K352N | Missense Mutation (SNP) | VAF 70/237 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.224); catalogued as COSV55129642; called by muse, mutect2, varscan2
- IL18BP | c.64C>T p.H22Y | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV52622545; called by muse, mutect2, varscan2
- IREB2 | c.970G>T p.G324W | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51922944; called by muse, mutect2, varscan2
- JMJD1C | c.5663G>C p.W1888S | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV59517558; called by muse, mutect2, varscan2
- KIAA0319 | c.3145G>C p.G1049R | Missense Mutation (SNP) | VAF 83/314 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV65501733; called by muse, mutect2, varscan2
- KIF11 | c.2390C>T p.S797F | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV53273554, COSV99037844; called by muse, mutect2
- KIF16B | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV100734745, COSV61712952; called by muse, mutect2, varscan2
- KRIT1 | c.1973T>A p.V658E | Missense Mutation (SNP) | VAF 61/240 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV60670164; called by muse, mutect2, varscan2
- MYH11 | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 95/347 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as COSV55567019; called by muse, mutect2, varscan2
- MYLK3 | c.2313T>A p.N771K | Missense Mutation (SNP) | VAF 81/264 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV67366418; called by muse, mutect2, varscan2
- NABP1 | c.292A>C p.K98Q | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57139375; called by muse, mutect2, varscan2
- NCOR1 | c.6211C>A p.Q2071K | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.204); catalogued as COSV51992622; called by muse, mutect2, varscan2
- NDC1 | c.1572T>G p.N524K | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV52338477; called by muse, mutect2, varscan2
- NEBL | c.2813A>G p.Y938C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as rs1024719266, COSV65805347; called by muse, mutect2, varscan2
- NSD3 | c.928G>T p.V310F | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57621623; called by muse, mutect2, varscan2
- OPA1 | c.1988T>C p.L663P (on ENST00000361510 / NM_130837.3; = p.L608P on NM_015560.3) | Missense Mutation (SNP) | VAF 83/249 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62483020; called by muse, mutect2, varscan2
- PLXDC1 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV59553543; called by muse, mutect2, varscan2
- RBM25 | c.1004G>C p.R335P | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.859); catalogued as COSV56202374; called by muse, mutect2, varscan2
- RFTN1 | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 118/266 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as COSV61922645; called by muse, mutect2, varscan2
- RICTOR | c.3967A>C p.S1323R | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57129361; called by muse, mutect2
- RNF4 | c.558C>A p.H186Q | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV58640762, COSV58642700; called by muse, mutect2, varscan2
- RPGRIP1L | c.1357G>C p.D453H | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV50915263; called by muse, mutect2, varscan2
- SH3TC2 | c.2739G>C p.K913N | Missense Mutation (SNP) | VAF 97/471 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as COSV60467243; called by muse, mutect2, varscan2
- SLC29A2 | c.164G>C p.S55T | Missense Mutation (SNP) | VAF 84/330 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.068); catalogued as COSV60804094; called by muse, mutect2, varscan2
- SLFN11 | c.1037A>C p.K346T | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV57700308; called by muse, mutect2, varscan2
- SP4 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV56024122; called by muse, mutect2, varscan2
- SPHK2 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV55341675; called by muse, mutect2, varscan2
- TAF1A | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 67/219 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.08); catalogued as COSV61919637; called by muse, mutect2, varscan2
- TAP1 | c.1608G>T p.E536D | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.735); catalogued as COSV62754054; called by muse, mutect2
- TAX1BP1 | c.2236T>A p.F746I | Missense Mutation (SNP) | VAF 78/270 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52244749; called by muse, mutect2, varscan2
- TBL1XR1 | c.531G>T p.W177C | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61792445; called by muse, mutect2, varscan2
- TNR | c.3776G>T p.S1259I | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs1457778369, COSV54875922, COSV54909245; called by muse, mutect2, varscan2
- TNRC6B | c.2063A>C p.E688A | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.952); catalogued as COSV57306169; called by muse, mutect2
- TTN | c.28348G>T p.G9450W (on ENST00000591111; = p.G8523W on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/402 reads (28%) | PolyPhen probably damaging (1); catalogued as COSV60297833; called by muse, mutect2, varscan2
- TUBG1 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as COSV52222741; called by muse, mutect2, varscan2
- XIRP2 | c.5605A>G p.R1869G (on ENST00000628543; = p.R2044G on NM_152381.6) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV54729680; called by muse, mutect2, varscan2
- ZEB2 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV57965028; called by muse, mutect2
- ZNF284 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV69691615; called by muse, mutect2, varscan2
- ZNF610 | c.1058T>A p.F353Y | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58346319; called by muse, mutect2, varscan2
- ZUP1 | c.427A>C p.K143Q | Missense Mutation (SNP) | VAF 70/249 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV63944720; called by muse, mutect2, varscan2
- ADAMTS12 | c.607del p.T203Pfs*8 | Frame Shift Del (DEL) | VAF 103/276 reads (37%) | called by mutect2, pindel, varscan2
- EPHA1 | c.843del p.S282Afs*58 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel
- FIP1L1 | c.466_467dup p.D156Efs*50 | Frame Shift Ins (INS) | VAF 57/202 reads (28%) | called by mutect2, pindel, varscan2
- GCC2 | c.3973del p.V1325Sfs*7 | Frame Shift Del (DEL) | VAF 65/255 reads (25%) | called by mutect2, pindel, varscan2
- GIGYF2 | c.2899_2902delinsT p.Q967_Q968delins* | Nonsense Mutation (DEL) | VAF 16/54 reads (30%) | called by pindel, varscan2*
- IGHV3-16 | c.287_288del p.N96Ifs*? | Frame Shift Del (DEL) | VAF 75/205 reads (37%) | called by mutect2, pindel, varscan2
- PARPBP | c.781del p.D261Tfs*3 | Frame Shift Del (DEL) | VAF 60/227 reads (26%) | called by mutect2, varscan2
- PI4KA | c.5442dup p.S1815* | Frame Shift Ins (INS) | VAF 12/47 reads (26%) | called by mutect2, varscan2
- AL035460.1 | c.15C>T p.C5= | Silent (SNP) | VAF 61/193 reads (32%) | catalogued as rs1434354776, COSV63028560; called by muse, mutect2, varscan2
- C1orf56 | c.753A>G p.Q251= | Silent (SNP) | VAF 62/227 reads (27%) | catalogued as COSV54848680; called by muse, mutect2, varscan2
- DAPK1 | c.714T>C p.D238= | Silent (SNP) | VAF 45/140 reads (32%) | catalogued as COSV63791349; called by muse, mutect2, varscan2
- DISC1 | c.1620G>A p.P540= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs148583596; called by muse, varscan2
- FCRL3 | c.1953C>T p.S651= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV63841033, COSV63844481; called by muse, mutect2, varscan2
- FLRT2 | c.873G>T p.L291= | Silent (SNP) | VAF 177/372 reads (48%) | catalogued as COSV58148927; called by muse, varscan2
- HELQ | c.945T>G p.P315= | Silent (SNP) | VAF 62/228 reads (27%) | catalogued as COSV55027357; called by muse, mutect2, varscan2
- KIF16B | c.3708A>C p.A1236= | Silent (SNP) | VAF 56/197 reads (28%) | catalogued as COSV61712963; called by muse, mutect2, varscan2
- ODF2 | c.1828C>T p.L610= (on ENST00000434106 / NM_153433.2; = p.L586= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as rs533246171, COSV63548670; called by muse, mutect2, varscan2
- OR2AG1 | c.279C>T p.S93= | Silent (SNP) | VAF 55/234 reads (24%) | catalogued as COSV56627091; called by muse, mutect2, varscan2
- OR5L2 | c.519G>C p.V173= | Silent (SNP) | VAF 22/662 reads (3%) | catalogued as COSV65724114, COSV65724989; called by muse, mutect2
- PAF1 | c.216T>C p.H72= | Silent (SNP) | VAF 88/241 reads (37%) | catalogued as rs778687735, COSV55394719, COSV55395954; called by muse, mutect2, varscan2
- PCDH1 | c.2475C>T p.L825= | Silent (SNP) | VAF 57/230 reads (25%) | catalogued as COSV54618714; called by muse, varscan2
- PCNX1 | c.2814G>A p.L938= | Silent (SNP) | VAF 76/228 reads (33%) | catalogued as COSV53100715; called by muse, mutect2, varscan2
- POC1B | c.303T>C p.H101= | Silent (SNP) | VAF 41/143 reads (29%) | catalogued as COSV57968240; called by muse, mutect2, varscan2
- RFC1 | c.702A>G p.E234= | Silent (SNP) | VAF 42/155 reads (27%) | catalogued as COSV62900901; called by muse, mutect2, varscan2
- RIN3 | c.1059C>A p.P353= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV53654541; called by muse, mutect2, varscan2
- SELL | c.282T>A p.P94= (on ENST00000650983; = p.P81= on NM_000655.5) | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV52554559; called by muse, mutect2, varscan2
- SPPL2C | c.963G>A p.P321= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs140813443; called by muse, mutect2, varscan2
- SYT10 | c.474G>A p.V158= | Silent (SNP) | VAF 154/554 reads (28%) | catalogued as rs111713819, COSV57344674; called by muse, varscan2
- SYT3 | c.73C>A p.R25= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as COSV58898745; called by muse, mutect2, varscan2
- TOM1 | c.342T>C p.H114= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV65899576; called by muse, mutect2, varscan2
- UBE3B | c.816T>C p.P272= | Silent (SNP) | VAF 54/173 reads (31%) | catalogued as COSV55097656; called by muse, mutect2, varscan2
- WASL | c.1398A>G p.G466= | Silent (SNP) | VAF 158/499 reads (32%) | catalogued as COSV56135831; called by muse, varscan2
- ZNF496 | c.1623C>G p.R541= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as COSV54181637; called by muse, varscan2
